Somatic mutation profile of tumor specimen TCGA-91-6840-01A (aliquot TCGA-91-6840-01A-11D-1945-08) from TCGA case TCGA-91-6840, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.8 years (21,854 days).
Specimen TCGA-91-6840-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6706798d-874b-4b44-a996-35b3c9a19aff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-6840-10A (Blood Derived Normal), aliquot TCGA-91-6840-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d41b4708-0ccc-474f-84c8-b85e2f5795dc

The open-access MAF lists 130 somatic variants for this specimen: 99 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 28, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 2, 3'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 16/24 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7201G>C p.D2401H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1278933361, COSV71294985; called by muse, mutect2, varscan2
- ABHD5 | c.46_47del p.R16Vfs*20 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs387906336; called by pindel, varscan2
- ADORA3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs764124230, COSV53986994; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2448G>C p.K816N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.941); catalogued as COSV51859203; called by muse, mutect2, varscan2
- APC | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV57348738, COSV57363838, COSV57384634; called by muse, mutect2, varscan2
- ARID4A | c.2851C>G p.L951V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.073); catalogued as rs1298015057, COSV62162648; called by muse, mutect2, varscan2
- B3GAT1 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV100438139, COSV57000915; called by muse, mutect2, varscan2
- BUB1B | c.588C>G p.F196L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.486); catalogued as COSV55016843; called by muse, mutect2, varscan2
- C2CD3 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs1170345600, COSV100486367, COSV58101429; called by muse, mutect2, varscan2
- C3orf56 | c.158C>A p.T53N | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV67756538; called by muse, mutect2, varscan2
- C6orf226 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV59035709; called by muse, mutect2, varscan2
- CCDC47 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1309060560, COSV56724869; called by muse, mutect2, varscan2
- CMYA5 | c.8194G>T p.D2732Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV71409669; called by muse, mutect2, varscan2
- DMRT1 | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66524793; called by muse, mutect2, varscan2
- DNAH5 | c.13774C>G p.R4592G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54210253, COSV54253592, COSV99455552; called by muse, mutect2, varscan2
- DNAH5 | c.6062-1G>A p.X2021_splice | Splice Site (SNP) | VAF 14/26 reads (54%) | catalogued as rs764893840, COSV54253602; called by muse, mutect2, varscan2
- DNAH8 | c.9868C>G p.L3290V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59482138; called by muse, mutect2
- EFNB2 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55364324, COSV55365093; called by muse, mutect2, varscan2
- ENTR1 | c.335G>C p.R112T (on ENST00000357365 / NM_001039707.2; = p.R89T on NM_006643.4) | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs922879446, COSV53743398; called by muse, mutect2
- ERMN | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779542501, COSV68075833; called by muse, mutect2, varscan2
- F2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV61316063; called by muse, mutect2, varscan2
- FAM20B | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as COSV55382787, COSV99762152, COSV99762700; called by muse, mutect2, varscan2
- FEZF2 | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV51864582; called by muse, mutect2, varscan2
- FLT3 | c.197C>A p.A66E | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV54046661, COSV54071297; called by muse, mutect2, varscan2
- FRMPD1 | c.4667G>A p.R1556H | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs202028346, COSV66699251; called by muse, mutect2, varscan2
- FZD10 | c.1677dup p.A560Sfs*13 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | catalogued as rs1294762337; called by mutect2, pindel, varscan2
- GALNT8 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52901964; called by muse, mutect2, varscan2
- GJA9 | c.996G>T p.E332D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs1406579601, COSV62531988; called by muse, mutect2, varscan2
- GLG1 | c.1343T>C p.I448T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52674761; called by muse, mutect2, varscan2
- GOSR2 | c.343C>T p.R115W (on ENST00000393456 / NM_001321134.1; = p.R180W on NM_004287.5) | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305687118, COSV56661283; called by muse, mutect2, varscan2
- GRIK1 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748055928, COSV58732786; called by muse, mutect2, varscan2
- GRK3 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.075); catalogued as rs780788559; called by muse, mutect2, varscan2
- HAPLN3 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs372680045; called by muse, mutect2, varscan2
- IL17D | c.399C>A p.S133R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59232005; called by muse, mutect2, varscan2
- ISM2 | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 75/88 reads (85%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.484); catalogued as COSV53637151; called by muse, mutect2, varscan2
- KCNQ2 | c.1908G>C p.K636N (on ENST00000359125 / NM_172107.4; = p.K608N on NM_004518.6) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60554690; called by muse, mutect2
- KIF14 | c.3582G>A p.M1194I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs1191938562, COSV66264239; called by muse, mutect2, varscan2
- LATS1 | c.1249C>G p.H417D | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.922); catalogued as rs748618436, COSV53600323; called by muse, mutect2, varscan2
- LGALSL | c.434T>C p.F145S | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV53230962; called by muse, mutect2, varscan2
- LNX2 | c.656C>G p.T219S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV60338768; called by muse, mutect2, varscan2
- LPAR4 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV70913485; called by muse, mutect2, varscan2
- MAP3K20 | c.939A>C p.R313S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV59106608; called by muse, mutect2, varscan2
- MLEC | c.574T>G p.Y192D | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as COSV57330471; called by muse, mutect2, varscan2
- MROH7 | c.1612C>G p.Q538E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV59878305; called by muse, mutect2, varscan2
- MTOR | c.3132G>A p.M1044I | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs532979867, COSV63878633; called by muse, mutect2, varscan2
- NAALAD2 | c.231A>C p.E77D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58966447; called by muse, mutect2, varscan2
- NBEA | c.6723C>G p.F2241L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV59798743, COSV59824639; called by muse, mutect2, varscan2
- NRP2 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55928958, COSV55935782; called by muse, mutect2, varscan2
- NXF1 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs548866961, COSV53673705; called by muse, mutect2, varscan2
- OR10H2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV59947134; called by muse, mutect2, varscan2
- PABPC4 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.074); catalogued as rs1188867236, COSV65724509; called by muse, mutect2, varscan2
- PCDH18 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV61272350; called by muse, mutect2, varscan2
- PCDHGB5 | c.1713C>A p.F571L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV54038321; called by muse, mutect2, varscan2
- PCNT | c.8934G>C p.M2978I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64033310; called by muse, mutect2, varscan2
- PKP2 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV50749603; called by muse, mutect2, varscan2
- PLA2G4D | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51824049; called by muse, mutect2, varscan2
- PLEC | c.12270G>A p.M4090I (on ENST00000322810 / NM_201380.4; = p.M3980I on NM_000445.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV59697623; called by muse, mutect2, varscan2
- PLEC | c.11434G>A p.E3812K (on ENST00000322810 / NM_201380.4; = p.E3702K on NM_000445.5) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV59697673; called by muse, mutect2, varscan2
- PML | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV51454714; called by muse, mutect2, varscan2
- PON2 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs1288057074, COSV56003710; called by muse, mutect2, varscan2
- POTEM | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 225/883 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); catalogued as COSV101304845, COSV69152148; called by muse, varscan2
- RAB3IL1 | c.866T>A p.V289E | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV57119074; called by muse, mutect2, varscan2
- RAD50 | c.3892G>C p.E1298Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1422137796, COSV54757971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGAPB | c.4156G>C p.E1386Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV53444602; called by muse, mutect2, varscan2
- RELN | c.4718C>T p.T1573M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762922371, COSV100634351, COSV59034920; called by muse, mutect2, varscan2
- REV3L | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62623728; called by muse, mutect2, varscan2
- RIOX1 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1423377904, COSV100408114, COSV58374579; called by muse, mutect2
- RNASE12 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs201559377, COSV60088418; called by muse, mutect2, varscan2
- SCLT1 | c.1695G>C p.E565D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV55413133; called by muse, mutect2
- SERPINB10 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV53075570; called by muse, mutect2, varscan2
- SGIP1 | c.1226C>A p.A409E | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs531131210, COSV52774122, COSV52781675; called by muse, mutect2, varscan2
- SIGLEC10 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV59486910; called by muse, mutect2, varscan2
- SLC25A16 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV56266276; called by muse, mutect2, varscan2
- SLC25A47 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as rs202229264, COSV64161748; called by muse, mutect2, varscan2
- SLC4A3 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.202); catalogued as COSV56097791; called by muse, mutect2
- SPINT2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs749590138, COSV56648985; called by muse, varscan2
- STMN1 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV63481486; called by muse, mutect2, varscan2
- STRIP2 | c.2211G>C p.Q737H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50809331; called by muse, mutect2, varscan2
- STX3 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV55701526; called by muse, mutect2, varscan2
- TMEM176A | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV50245276; called by muse, mutect2, varscan2
- TMEM184B | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as rs934830159, COSV62674402; called by muse, mutect2, varscan2
- TRIP11 | c.1029G>C p.K343N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV50964157; called by muse, mutect2, varscan2
- TRMT9B | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs570175321, COSV71600274; called by muse, mutect2, varscan2
- TTC3 | c.3406G>C p.E1136Q | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV61296533; called by muse, mutect2, varscan2
- TTLL6 | c.2600G>A p.R867K (on ENST00000393382 / NM_001130918.3; = p.R560K on NM_173623.3) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV64979702; called by muse, mutect2, varscan2
- TTN | c.12217G>C p.E4073Q (on ENST00000591111; = p.E4027Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV60158190; called by muse, mutect2, varscan2
- UBA2 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV55828827, COSV55830777; called by muse, mutect2, varscan2
- UBR4 | c.13391-1G>C p.X4464_splice | Splice Site (SNP) | VAF 26/162 reads (16%) | catalogued as COSV64399763; called by muse, mutect2, varscan2
- VCAM1 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV54122194; called by muse, mutect2
- VCAM1 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs772033172, COSV54119977; called by muse, mutect2, varscan2
- VWA8 | c.3124C>A p.L1042M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV65000745; called by muse, mutect2, varscan2
- ZC4H2 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.911); catalogued as COSV62006284; called by muse, mutect2, varscan2
- ZNF552 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.362); catalogued as COSV66971974; called by muse, mutect2, varscan2
- ZNF664 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867198698, COSV61878952; called by muse, mutect2, varscan2
- F5 | c.585dup p.G196Rfs*5 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- FIGN | c.823del p.L275Cfs*26 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.100_107del p.I34Ffs*26 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- ITGA3 | c.776del p.F259Sfs*11 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ABCA10 | c.1327T>C p.L443= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1475923809; called by mutect2, varscan2
- ARMH4 | c.273G>C p.S91= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV50762857, COSV50774834; called by muse, mutect2, varscan2
- CCDC183 | c.588C>T p.L196= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as rs199891165; called by muse, mutect2, varscan2
- DENND4C | c.5808G>A p.Q1936= (on ENST00000434457 / NM_001330640.2; = p.Q1887= on NM_017925.7) | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV59548865; called by muse, mutect2, varscan2
- ENG | c.1329C>G p.L443= | Silent (SNP) | VAF 38/208 reads (18%) | catalogued as COSV61229076; called by muse, mutect2, varscan2
- FFAR3 | c.195G>A p.L65= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV100588320; called by muse, mutect2, varscan2
- GLYAT | c.306A>G p.L102= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV53540731; called by muse, mutect2, varscan2
- KDELR1 | c.489C>G p.L163= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV58102991; called by muse, mutect2, varscan2
- KMT5A | c.970C>A p.R324= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV57863520, COSV57864994; called by muse, mutect2, varscan2
- LSG1 | c.90T>A p.T30= | Silent (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- MPDZ | c.5091G>A p.L1697= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV59918477; called by muse, mutect2
- MROH5 | c.3927G>A p.Q1309= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1168259934, COSV61472912; called by muse, mutect2, varscan2
- NOMO1 | c.2712C>T p.S904= | Silent (SNP) | VAF 53/196 reads (27%) | catalogued as COSV55061540; called by muse, mutect2
- OR14J1 | c.306C>T p.F102= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as COSV65845986; called by muse, mutect2
- PCDHA5 | c.2139G>A p.T713= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV65358056; called by muse, mutect2, varscan2
- PCDHA9 | c.63C>T p.L21= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs146722772; called by muse, mutect2, varscan2
- PCDHGA7 | c.2121C>T p.F707= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV53941037; called by muse, mutect2, varscan2
- PDE10A | c.336C>T p.I112= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV63096761, COSV63106697; called by muse, mutect2, varscan2
- POLR2A | c.5868C>A p.L1956= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.252G>T p.G84= | Silent (SNP) | VAF 43/420 reads (10%) | called by muse, mutect2, varscan2
- PRIM1 | c.849C>T p.I283= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- SLC12A9 | c.2238C>T p.L746= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV51937277; called by muse, mutect2, varscan2
- SLC20A1 | c.2039G>A p.*680= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV55613209; called by muse, mutect2, varscan2
- SLC35G5 | c.693G>T p.L231= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs754536208, COSV55315439; called by muse, mutect2, varscan2
- SLC5A9 | c.1311G>T p.L437= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV52585870; called by muse, mutect2, varscan2
- SLC9B1 | c.178C>T p.L60= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV56474297, COSV56475750; called by muse, mutect2, varscan2
- SYNE1 | c.18456G>A p.L6152= (on ENST00000367255 / NM_182961.4; = p.L6081= on NM_033071.3) | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV55109938; called by muse, mutect2, varscan2
- USH2A | c.6627A>G p.L2209= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV56441013; called by muse, mutect2, varscan2
- AC073310.1 | n.1029A>T | RNA (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- CAPN3 | c.380-476G>A | Intron (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- STRN | c.*1C>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | catalogued as rs761581256, COSV55748256; called by muse, mutect2, varscan2
